Somatic mutation profile of tumor specimen TCGA-DD-AADJ-01A (aliquot TCGA-DD-AADJ-01A-11D-A40R-10) from TCGA case TCGA-DD-AADJ, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 70.8 years (25,863 days).
Specimen TCGA-DD-AADJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 497bfa04-09f0-4096-b219-3ba642461f36.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AADJ-10A (Blood Derived Normal), aliquot TCGA-DD-AADJ-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8cd5f85b-0ce1-4ae4-b62a-b9f0bb506a42

The open-access MAF lists 68 somatic variants for this specimen: 52 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 14, Frame Shift Del 5, Splice Site 1, 3'UTR 1, In Frame Del 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.241G>T p.G81C | Missense Mutation (SNP) | VAF 36/80 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67960075, COSV67960449, COSV67960680; called by muse, mutect2, varscan2
- ABCB4 | c.1039G>A p.V347I | Missense Mutation (SNP) | VAF 806/1833 reads (44%) | SIFT tolerated (0.91); PolyPhen benign (0.007); catalogued as rs1487551764, COSV99709723; called by muse, mutect2, varscan2
- ABCD4 | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 132/290 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV100084007; called by muse, varscan2
- ACAN | c.5666C>T p.S1889F | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); catalogued as COSV61360828; called by muse, mutect2, varscan2
- AHNAK2 | c.14347A>G p.I4783V | Missense Mutation (SNP) | VAF 69/162 reads (43%) | SIFT tolerated (0.95); PolyPhen benign (0.005); catalogued as rs760249288, COSV100315545; called by muse, mutect2, varscan2
- AHNAK2 | c.13324A>G p.S4442G | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs377277155, COSV100315547; called by muse, mutect2, varscan2
- ARVCF | c.1642G>T p.D548Y | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99598928; called by muse, mutect2, varscan2
- C8A | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 68/99 reads (69%) | SIFT deleterious (0.02); PolyPhen benign (0.276); catalogued as rs768726327, COSV100776436; called by muse, varscan2
- CACNA1F | c.3142C>G p.P1048A | Missense Mutation (SNP) | VAF 107/282 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.342); catalogued as rs1557107461, COSV100544348; called by muse, mutect2, varscan2
- CNTNAP2 | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as rs751589771, COSV62182713; called by muse, mutect2, varscan2
- CRMP1 | c.896C>A p.A299E | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100271325; called by muse, mutect2
- CRMP1 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100271327; called by muse, mutect2
- CXorf56 | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 90/253 reads (36%) | catalogued as COSV100233324; called by muse, mutect2, varscan2
- CYP2B6 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100137290; called by muse, mutect2, varscan2
- DDB1 | c.928A>G p.I310V | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.603); catalogued as rs367862166; called by muse, mutect2, varscan2
- DOCK3 | c.5729G>A p.R1910H | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.976); catalogued as rs781974113, COSV56522801; called by muse, mutect2, varscan2
- DSCAM | c.2782T>C p.S928P | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV101259089; called by muse, mutect2, varscan2
- EML4 | c.2731G>A p.E911K | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.257); catalogued as COSV100580697; called by muse, mutect2, varscan2
- ERLIN2 | c.*6del | Frame Shift Del (DEL) | VAF 42/126 reads (33%) | catalogued as COSV99379658; called by mutect2, pindel, varscan2
- ERVFRD-1 | c.734G>A p.G245E | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs558720062, COSV100977341; called by muse, mutect2, varscan2
- FERMT2 | c.1573C>T p.R525C | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); catalogued as rs747430958, COSV58409126; called by muse, mutect2, varscan2
- FIBCD1 | c.826C>A p.R276S | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV99446724; called by muse, mutect2, varscan2
- IL1RAPL2 | c.983A>T p.N328I | Missense Mutation (SNP) | VAF 178/416 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100780724; called by muse, mutect2, varscan2
- KLHL41 | c.1174G>A p.G392S | Missense Mutation (SNP) | VAF 67/131 reads (51%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.875); catalogued as rs374204816; called by muse, mutect2, varscan2
- LZTS1 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as COSV56116105; called by muse, mutect2, varscan2
- METTL18 | c.866T>G p.L289R | Missense Mutation (SNP) | VAF 96/336 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99609390; called by muse, mutect2, varscan2
- MTHFSD | c.338G>A p.C113Y (on ENST00000360900 / NM_001159377.2; = p.C112Y on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/65 reads (62%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV100530313; called by muse, mutect2, varscan2
- NLGN1 | c.1207G>A p.D403N | Missense Mutation (SNP) | VAF 65/156 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs371578371; called by muse, mutect2, varscan2
- OR5V1 | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.416); catalogued as COSV65828689; called by muse, mutect2, varscan2
- PCSK2 | c.1790C>T p.A597V | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.265); catalogued as COSV52726964; called by muse, mutect2, varscan2
- PHPT1 | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs751950321, COSV99915397, COSV99915694; called by muse, mutect2, varscan2
- PI16 | c.710C>A p.A237E | Missense Mutation (SNP) | VAF 71/146 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV101028597, COSV65448058; called by muse, mutect2, varscan2
- PLTP | c.267G>A p.M89I | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV100819045; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.793G>C p.A265P | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.137); catalogued as COSV99460788; called by muse, mutect2, varscan2
- PQBP1 | c.185T>G p.L62R | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.96); PolyPhen probably damaging (0.998); catalogued as COSV99504039; called by muse, mutect2, varscan2
- PRICKLE4 | c.95A>T p.Q32L (on ENST00000359201; = p.Q72L on NM_013397.6) | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV100138621; called by muse, mutect2, varscan2
- SAMD9 | c.3814G>T p.D1272Y | Missense Mutation (SNP) | VAF 68/179 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as COSV101180125; called by muse, mutect2, varscan2
- SLC12A3 | c.2030T>C p.V677A | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV99343822; called by muse, mutect2
- SLC24A2 | c.832G>A p.V278I | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1267656135, COSV53867567, COSV53876900; called by muse, mutect2, varscan2
- SNW1 | c.1143G>C p.Q381H | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.585); catalogued as COSV53174810; called by muse, mutect2, varscan2
- TAPBP | c.1232A>G p.E411G | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101444919; called by muse, mutect2, varscan2
- TASOR | c.2749C>A p.L917M (on ENST00000355628 / NM_001365636.2; = p.L521M on NM_015224.3) | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100843330; called by muse, mutect2, varscan2
- THRB | c.764T>C p.I255T | Missense Mutation (SNP) | VAF 59/163 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs1385080780, COSV99769235; called by muse, mutect2, varscan2
- TIMP1 | c.389G>T p.S130I | Missense Mutation (SNP) | VAF 80/184 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV99512094; called by muse, mutect2, varscan2
- XIRP2 | c.7492T>A p.C2498S (on ENST00000628543; = p.C2673S on NM_152381.6) | Missense Mutation (SNP) | VAF 189/372 reads (51%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99738398; called by muse, mutect2, varscan2
- ZNF420 | c.711A>C p.Q237H | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.86); PolyPhen benign (0.018); catalogued as rs764798559, COSV100421144; called by muse, mutect2, varscan2
- ACAD11 | c.1279del p.M427Wfs*25 | Frame Shift Del (DEL) | VAF 87/241 reads (36%) | called by mutect2, pindel, varscan2
- ATP6V1D | c.30del p.S12Rfs*8 | Frame Shift Del (DEL) | VAF 34/78 reads (44%) | called by mutect2, pindel, varscan2
- C1orf35 | c.246-6_275del p.X82_splice | Splice Site (DEL) | VAF 18/80 reads (23%) | called by mutect2, pindel
- EHMT2 | c.1589del p.M530Rfs*17 | Frame Shift Del (DEL) | VAF 57/140 reads (41%) | called by mutect2, pindel, varscan2
- FN1 | c.183_186del p.Q63Sfs*7 | Frame Shift Del (DEL) | VAF 34/71 reads (48%) | called by mutect2, pindel, varscan2
- MCM3 | c.1120_1134del p.R374_T378del (on ENST00000229854 / NM_001366374.2; = p.R364_T368del on NM_002388.6 and 5 other RefSeq transcripts) | In Frame Del (DEL) | VAF 18/68 reads (26%) | called by mutect2, pindel, varscan2
- ACO1 | c.1674A>T p.I558= | Silent (SNP) | VAF 76/166 reads (46%) | catalogued as COSV100007660; called by muse, mutect2, varscan2
- AGTPBP1 | c.843C>T p.N281= | Silent (SNP) | VAF 55/103 reads (53%) | catalogued as COSV100429229; called by muse, mutect2, varscan2
- ARHGEF17 | c.2187G>A p.E729= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV99734859; called by muse, mutect2, varscan2
- CD40LG | c.753T>C p.T251= | Silent (SNP) | VAF 505/1327 reads (38%) | catalogued as COSV101033421; called by muse, mutect2, varscan2
- CEP128 | c.2991A>G p.G997= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV99823644; called by muse, mutect2, varscan2
- FAM163B | c.397C>T p.L133= | Silent (SNP) | VAF 42/118 reads (36%) | catalogued as COSV63205189; called by muse, mutect2, varscan2
- GULP1 | c.534A>G p.T178= | Silent (SNP) | VAF 158/486 reads (33%) | catalogued as COSV100770181; called by muse, mutect2, varscan2
- KCTD3 | c.822G>A p.V274= | Silent (SNP) | VAF 34/108 reads (31%) | catalogued as COSV99378794; called by muse, mutect2, varscan2
- PCDHGA4 | c.1203C>T p.N401= | Silent (SNP) | VAF 43/107 reads (40%) | catalogued as rs1396473104, COSV99530578; called by muse, mutect2, varscan2
- PRPF8 | c.1548G>T p.L516= | Silent (SNP) | VAF 28/53 reads (53%) | catalogued as COSV100517130; called by muse, mutect2, varscan2
- RYBP | c.543A>T p.A181= | Silent (SNP) | VAF 49/126 reads (39%) | catalogued as COSV101523275; called by muse, mutect2, varscan2
- SLC4A3 | c.87A>T p.P29= | Silent (SNP) | VAF 90/207 reads (43%) | catalogued as COSV99812396; called by muse, mutect2, varscan2
- TGDS | c.39C>T p.P13= | Silent (SNP) | VAF 72/166 reads (43%) | catalogued as COSV99724940; called by muse, mutect2, varscan2
- USH2A | c.14064A>G p.L4688= | Silent (SNP) | VAF 56/224 reads (25%) | catalogued as COSV100228909; called by muse, mutect2, varscan2
- DST | c.4297-1701del | Intron (DEL) | VAF 34/101 reads (34%) | called by mutect2, pindel, varscan2
- LARS2 | c.*374A>G | 3'UTR (SNP) | VAF 56/164 reads (34%) | catalogued as rs914797921, COSV99647398; called by muse, mutect2, varscan2
